Somatic mutation profile of tumor specimen 0DRGF0 from CCDI case PBCGLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 17.6 years (6,426 days).
Specimen 0DRGF0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27ecaf05-c43e-4885-bdd8-eef85f19a882.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRGEL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060b5495-5d9d-4562-8436-d833f962fd26

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 128/1382 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs748026747, COSV67417698; called by muse, mutect2
- TNS1 | c.4486G>A p.A1496T | Missense Mutation (SNP) | VAF 102/1842 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50704601; called by muse, mutect2
- FNDC1 | c.3275G>C p.R1092P | Missense Mutation (SNP) | VAF 356/977 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- KHNYN | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 74/1014 reads (7%) | called by muse, mutect2
- TRHDE | c.2700A>T p.L900F | Missense Mutation (SNP) | VAF 42/1752 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SF3A3 | c.468+20A>T | Intron (SNP) | VAF 382/884 reads (43%) | called by muse, mutect2, varscan2
